Somatic mutation profile of tumor specimen TCGA-T3-A92N-01A (aliquot TCGA-T3-A92N-01A-11D-A391-08) from TCGA case TCGA-T3-A92N, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 79.1 years (28,879 days).
Specimen TCGA-T3-A92N-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 70ed5211-cd08-4dfe-9ee9-291f9de98118.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-T3-A92N-10A (Blood Derived Normal), aliquot TCGA-T3-A92N-10A-01D-A394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/57a8ce36-6fc6-4c86-a5b0-a2b949a1625c

The open-access MAF lists 185 somatic variants for this specimen: 135 protein-altering or splice-affecting, 44 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 108, Silent 44, Nonsense Mutation 15, Frame Shift Ins 4, Frame Shift Del 4, Splice Region 3, Intron 3, RNA 2, Splice Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PRKAR1A | c.1102C>T p.R368* | Nonsense Mutation (SNP) | VAF 22/108 reads (20%) | catalogued as rs387906692, CM114572, COSV56838441; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCC1 | c.3319G>T p.V1107F | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as COSV100579569; called by muse, mutect2, varscan2
- ACSM2B | c.1301C>T p.A434V | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.052); catalogued as COSV100312679; called by muse, mutect2, varscan2
- ADGRG1 | c.1120C>T p.Q374* | Nonsense Mutation (SNP) | VAF 44/130 reads (34%) | catalogued as COSV101113415; called by muse, mutect2, varscan2
- ADGRL1 | c.1933G>C p.V645L (on ENST00000340736 / NM_001008701.3; = p.V640L on NM_014921.5) | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs746006001, COSV100529530; called by muse, mutect2, varscan2
- AKAP7 | c.250C>G p.Q84E | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.48); catalogued as COSV100818782; called by muse, mutect2, varscan2
- AL592490.1 | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV101308197; called by muse, mutect2
- ANK3 | c.10744A>G p.T3582A | Missense Mutation (SNP) | VAF 55/108 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV99028270, COSV99780030; called by muse, mutect2, varscan2
- ANKRD28 | c.2374T>G p.L792V | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.923); catalogued as COSV101080660; called by muse, mutect2, varscan2
- ARAP1 | c.1361A>G p.N454S (on ENST00000393609 / NM_001040118.2; = p.N209S on NM_015242.4) | Missense Mutation (SNP) | VAF 110/156 reads (71%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV100501915; called by muse, mutect2, varscan2
- ARHGEF15 | c.707G>A p.R236K | Missense Mutation (SNP) | VAF 69/97 reads (71%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs777579935, COSV100730048; called by muse, mutect2, varscan2
- ARID5A | c.1645G>A p.A549T | Missense Mutation (SNP) | VAF 50/198 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs544853265, COSV100673590; called by muse, mutect2, varscan2
- ASAH2 | c.1394G>C p.G465A | Missense Mutation (SNP) | VAF 54/212 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV100269943; called by muse, mutect2, varscan2
- ATP1A3 | c.3022C>T p.R1008C (on ENST00000545399 / NM_001256214.2; = p.R995C on NM_152296.5) | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57485526, COSV57486287; called by muse, mutect2, varscan2
- AXIN1 | c.1249C>T p.R417C | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as rs746262710, COSV99249796; called by muse, mutect2, varscan2
- BRCA2 | c.8582G>C p.R2861T | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.382); catalogued as COSV101204237; called by muse, mutect2, varscan2
- C2CD5 | c.256A>C p.I86L | Missense Mutation (SNP) | VAF 96/188 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100448756; called by muse, mutect2, varscan2
- CCDC142 | c.1289C>A p.T430N (on ENST00000393965 / NM_001365575.2; = p.T423N on NM_032779.4) | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99282184; called by muse, mutect2, varscan2
- CCN2 | c.949A>T p.M317L | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV100915318, COSV100915349; called by muse, mutect2, varscan2
- CCSER2 | c.1358C>T p.P453L | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT tolerated (0.92); PolyPhen benign (0.001); catalogued as rs1177451114, COSV99825961; called by muse, mutect2, varscan2
- CD5L | c.187C>T p.R63W | Missense Mutation (SNP) | VAF 91/162 reads (56%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.806); catalogued as rs749053734, COSV63820970, COSV63822649; called by muse, mutect2, varscan2
- CELSR1 | c.3811C>T p.R1271C | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); catalogued as rs531245611, COSV99418325; called by muse, mutect2, varscan2
- CHD9 | c.6173C>G p.S2058C | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.315); catalogued as COSV99529172; called by muse, mutect2, varscan2
- CLTC | c.4349C>T p.P1450L | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV99292298; called by muse, mutect2, varscan2
- COL11A1 | c.3323G>T p.G1108V | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100616584; called by muse, mutect2, varscan2
- CPM | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 35/91 reads (38%) | catalogued as COSV100615088; called by muse, mutect2, varscan2
- CRYGD | c.409T>C p.S137P | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100006053; called by muse, mutect2, varscan2
- CSE1L | c.2308A>G p.I770V | Missense Mutation (SNP) | VAF 65/131 reads (50%) | SIFT tolerated (0.51); PolyPhen benign (0.11); catalogued as rs1430725843, COSV99522022; called by muse, mutect2, varscan2
- CYP51A1 | c.1026dup p.C343Mfs*19 | Frame Shift Ins (INS) | VAF 71/226 reads (31%) | catalogued as rs746385504; called by mutect2, varscan2
- DAGLA | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as COSV99944388, COSV99944436; called by muse, mutect2, varscan2
- DDX46 | c.2777A>G p.N926S | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV100844877; called by muse, mutect2, varscan2
- DNAH12 | c.763G>A p.A255T | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs373483492, COSV100244528; called by muse, mutect2, varscan2
- DNAH2 | c.8302C>T p.R2768C | Missense Mutation (SNP) | VAF 48/83 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770708165, COSV66721146; called by muse, mutect2, varscan2
- DNAJB9 | c.550T>A p.S184T | Missense Mutation (SNP) | VAF 43/94 reads (46%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV99974499; called by muse, mutect2, varscan2
- DNAJC14 | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.041); catalogued as rs746111800, COSV100423598; called by muse, mutect2, varscan2
- DNTTIP2 | c.994C>T p.Q332* | Nonsense Mutation (SNP) | VAF 12/51 reads (24%) | catalogued as COSV100785167; called by muse, mutect2, varscan2
- DOCK1 | c.562C>T p.H188Y | Missense Mutation (SNP) | VAF 60/117 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV54734149; called by muse, mutect2, varscan2
- EIF3A | c.1774G>A p.E592K | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.1); catalogued as COSV100974615, COSV64960480; called by muse, mutect2, varscan2
- EIF4G1 | c.2861G>A p.R954Q (on ENST00000346169 / NM_198241.3; = p.R759Q on NM_004953.5) | Missense Mutation (SNP) | VAF 26/154 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as COSV100071803; called by muse, mutect2, varscan2
- ETV1 | c.142C>T p.Q48* | Nonsense Mutation (SNP) | VAF 7/51 reads (14%) | catalogued as COSV99623484; called by muse, mutect2
- FARSB | c.343G>T p.A115S | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as COSV99918392; called by muse, mutect2, varscan2
- FRA10AC1 | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.15); catalogued as COSV100784707, COSV63274087; called by muse, mutect2
- GAPVD1 | c.2539T>A p.Y847N (on ENST00000394104; = p.Y874N on NM_015635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 64/118 reads (54%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.979); catalogued as COSV99783204; called by muse, mutect2, varscan2
- GATA1 | c.839A>C p.N280T | Missense Mutation (SNP) | VAF 28/41 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100936785; called by muse, mutect2, varscan2
- GLG1 | c.1209G>A p.M403I | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.035); catalogued as rs1460673226, COSV99215780; called by muse, mutect2, varscan2
- GNPAT | c.17C>T p.S6L | Missense Mutation (SNP) | VAF 69/125 reads (55%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.037); catalogued as COSV100009594, COSV100009763; called by muse, mutect2, varscan2
- GOLGA5 | c.191C>T p.S64L | Missense Mutation (SNP) | VAF 40/76 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as COSV50831951, COSV99370938; called by muse, mutect2, varscan2
- GTPBP3 | c.665-5C>G | Splice Region (SNP) | VAF 18/57 reads (32%) | catalogued as COSV99344492; called by muse, mutect2, varscan2
- H2BC1 | c.326C>T p.A109V | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.977); catalogued as COSV99219406; called by muse, mutect2, varscan2
- HERPUD2 | c.359C>G p.S120* | Nonsense Mutation (SNP) | VAF 5/109 reads (5%) | catalogued as COSV100257965; called by muse, mutect2
- HMX3 | c.1045T>G p.S349A | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV100774143; called by muse, mutect2, varscan2
- HOXD3 | c.154C>T p.P52S | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV50880952; called by muse, mutect2, varscan2
- IPO7 | c.1807G>C p.D603H | Missense Mutation (SNP) | VAF 26/36 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100797818; called by muse, mutect2, varscan2
- KBTBD7 | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.966); catalogued as rs1165236874, COSV65266312; called by muse, mutect2, varscan2
- KIF20B | c.4271A>G p.N1424S (on ENST00000371728 / NM_001284259.2; = p.N1384S on NM_016195.4) | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.031); catalogued as COSV99590034; called by muse, mutect2, varscan2
- KMT2D | c.4081C>T p.Q1361* | Nonsense Mutation (SNP) | VAF 136/322 reads (42%) | catalogued as COSV56429050; called by muse, mutect2, varscan2
- KMT2E | c.4099C>G p.Q1367E | Missense Mutation (SNP) | VAF 43/135 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as COSV57571945; called by muse, mutect2, varscan2
- KPNB1 | c.994A>C p.K332Q | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV99268111; called by muse, mutect2, varscan2
- LAG3 | c.784C>A p.L262M | Missense Mutation (SNP) | VAF 44/221 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.975); catalogued as COSV52566742; called by muse, mutect2, varscan2
- LCT | c.830T>C p.F277S | Missense Mutation (SNP) | VAF 32/46 reads (70%) | SIFT deleterious (0); PolyPhen benign (0.184); catalogued as COSV99929516; called by muse, mutect2, varscan2
- LONRF2 | c.1477-1G>A p.X493_splice | Splice Site (SNP) | VAF 47/101 reads (47%) | catalogued as COSV101110936; called by muse, mutect2, varscan2
- LTA4H | c.118G>A p.A40T | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as COSV99957097; called by muse, mutect2, varscan2
- LYZL1 | c.511T>A p.Y171N (on ENST00000375500; = p.Y125N on NM_032517.6) | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.07); catalogued as COSV100973638; called by muse, mutect2, varscan2
- MAP3K2 | c.1162C>T p.Q388* | Nonsense Mutation (SNP) | VAF 35/182 reads (19%) | catalogued as COSV100777234; called by muse, mutect2, varscan2
- MAST1 | c.2305G>A p.G769S | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated, low confidence (0.21); PolyPhen possibly damaging (0.493); catalogued as COSV99262962; called by muse, mutect2, varscan2
- MAST2 | c.858A>T p.E286D | Missense Mutation (SNP) | VAF 39/133 reads (29%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.048); catalogued as COSV100788120; called by muse, mutect2, varscan2
- MC1R | c.562G>A p.V188I | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.179); catalogued as rs774680166, COSV59626514; called by muse, mutect2, varscan2
- METTL8 | c.737G>A p.R246K | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT tolerated (0.05); PolyPhen benign (0.253); catalogued as rs768040586, COSV100931026; called by muse, mutect2, varscan2
- MTMR1 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 31/55 reads (56%) | SIFT tolerated (0.08); PolyPhen benign (0.445); catalogued as COSV100953943; called by muse, mutect2, varscan2
- MUC16 | c.41754C>T p.T13918= | Splice Region (SNP) | VAF 9/35 reads (26%) | catalogued as rs755849764, COSV66689741; called by muse, varscan2
- MUC4 | c.2951C>T p.S984L | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.316); catalogued as rs374537854; called by muse, mutect2
- MYO5C | c.4489T>G p.Y1497D | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99954749; called by muse, mutect2, varscan2
- NAA35 | c.2144C>T p.A715V | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.78); PolyPhen benign (0.006); catalogued as COSV100863349; called by muse, mutect2, varscan2
- NCOA2 | c.1729A>T p.M577L | Missense Mutation (SNP) | VAF 33/190 reads (17%) | SIFT tolerated (0.9); PolyPhen benign (0.006); catalogued as rs756518286, COSV101475982; called by muse, mutect2, varscan2
- NDRG2 | c.759C>T p.L253= (on ENST00000298687 / NM_001354570.1; = p.L239= on NM_016250.3 and 2 other RefSeq transcripts) | Splice Region (SNP) | VAF 21/68 reads (31%) | catalogued as COSV100069007; called by muse, mutect2, varscan2
- NFE2L2 | c.245A>T p.E82V | Missense Mutation (SNP) | VAF 77/116 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67960018, COSV67961061, COSV67962846; called by muse, mutect2, varscan2
- NFE2L3 | c.1315C>G p.H439D | Missense Mutation (SNP) | VAF 71/175 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as COSV99283713; called by muse, mutect2, varscan2
- NIN | c.1042A>T p.N348Y | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99813565; called by muse, mutect2, varscan2
- NOTCH3 | c.4285G>C p.E1429Q | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.87); PolyPhen benign (0.018); catalogued as COSV99657245; called by muse, mutect2
- NPHP4 | c.3253G>A p.E1085K | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs1479758700, COSV100976910; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NPR3 | c.443C>T p.S148L | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.717); catalogued as COSV54086734, COSV54090126; called by muse, mutect2, varscan2
- NRG3 | c.571G>T p.A191S | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV100931452; called by muse, mutect2, varscan2
- OR10Z1 | c.895A>G p.T299A | Missense Mutation (SNP) | VAF 35/204 reads (17%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV63526119; called by muse, mutect2, varscan2
- OR2L2 | c.76G>A p.V26I | Missense Mutation (SNP) | VAF 21/148 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs376676364, COSV63547837; called by muse, mutect2, varscan2
- OR8B4 | c.176T>A p.M59K | Missense Mutation (SNP) | VAF 42/54 reads (78%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.772); catalogued as COSV100635818; called by muse, mutect2, varscan2
- PCDHA12 | c.182C>T p.P61L | Missense Mutation (SNP) | VAF 68/155 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.684); catalogued as COSV56484857; called by muse, mutect2, varscan2
- PCDHGB1 | c.1477G>A p.E493K | Missense Mutation (SNP) | VAF 55/121 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.208); catalogued as rs759972486, COSV99538485, COSV99538722; called by muse, mutect2, varscan2
- PLCB1 | c.2773A>T p.K925* | Nonsense Mutation (SNP) | VAF 13/68 reads (19%) | catalogued as COSV100571047; called by muse, mutect2, varscan2
- PLK4 | c.2320G>A p.E774K | Missense Mutation (SNP) | VAF 33/48 reads (69%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV54636169, COSV99584653; called by muse, mutect2, varscan2
- POT1 | c.1510A>G p.K504E | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.275); catalogued as rs763189486, COSV100714062; called by muse, mutect2, varscan2
- PPARGC1B | c.89C>A p.S30Y | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.208); catalogued as COSV100494752; called by muse, mutect2, varscan2
- PPM1B | c.352C>T p.R118C | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs368246958; called by muse, mutect2, varscan2
- PPP1R18 | c.265C>T p.R89* | Nonsense Mutation (SNP) | VAF 15/31 reads (48%) | catalogued as COSV99223722; called by muse, mutect2, varscan2
- PTCH1 | c.2896G>A p.A966T | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as rs1253559528, COSV59479221; called by muse, mutect2, varscan2
- RALGAPA1 | c.2077C>T p.Q693* | Nonsense Mutation (SNP) | VAF 169/207 reads (82%) | catalogued as COSV99354796; called by muse, mutect2, varscan2
- RALYL | c.451C>T p.R151C | Missense Mutation (SNP) | VAF 31/44 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs527942610, COSV72822111, COSV72822148; called by muse, mutect2, varscan2
- RASA1 | c.934G>T p.E312* | Nonsense Mutation (SNP) | VAF 19/63 reads (30%) | catalogued as COSV57196502; called by muse, mutect2
- RNF111 | c.1315G>A p.E439K | Missense Mutation (SNP) | VAF 161/403 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.664); catalogued as COSV100789068; called by muse, mutect2, varscan2
- RNF17 | c.2332A>C p.K778Q | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99693247; called by muse, mutect2, varscan2
- RPTN | c.1379G>A p.S460N | Missense Mutation (SNP) | VAF 176/670 reads (26%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.478); catalogued as rs779011032, COSV60166040; called by muse, varscan2
- RTP4 | c.694A>G p.I232V | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0); catalogued as COSV99372300; called by muse, mutect2, varscan2
- RUNX1T1 | c.1690C>A p.P564T (on ENST00000265814 / NM_001198628.1; = p.P537T on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV56160129, COSV56160780; called by muse, mutect2, varscan2
- SELP | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 42/76 reads (55%) | SIFT tolerated (0.16); PolyPhen benign (0.271); catalogued as COSV99739978; called by muse, mutect2, varscan2
- SENP7 | c.1635del p.K545Nfs*11 | Frame Shift Del (DEL) | VAF 8/43 reads (19%) | catalogued as rs764980440, COSV58616367; called by mutect2, pindel, varscan2
- SH3TC2 | c.2835G>T p.M945I | Missense Mutation (SNP) | VAF 18/239 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as COSV100101725; called by muse, mutect2
- SIRT1 | c.1669G>A p.D557N | Missense Mutation (SNP) | VAF 77/126 reads (61%) | SIFT tolerated (0.45); PolyPhen benign (0.02); catalogued as rs919162147, COSV99281804; called by muse, mutect2, varscan2
- SLC25A2 | c.561C>G p.F187L | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as COSV99508253; called by muse, mutect2, varscan2
- SLC6A5 | c.1049C>A p.A350D | Missense Mutation (SNP) | VAF 73/106 reads (69%) | SIFT tolerated (0.11); PolyPhen benign (0.281); catalogued as COSV100116896; called by muse, mutect2, varscan2
- SLCO1A2 | c.584A>G p.Y195C | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100261913; called by muse, mutect2, varscan2
- SPHKAP | c.3760C>A p.P1254T | Missense Mutation (SNP) | VAF 41/64 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100764128; called by muse, mutect2, varscan2
- SPTA1 | c.5518G>A p.A1840T | Missense Mutation (SNP) | VAF 52/106 reads (49%) | SIFT tolerated (0.64); PolyPhen benign (0.033); catalogued as rs1183748687, COSV100934972; called by muse, mutect2, varscan2
- SRRM5 | c.2126C>A p.S709* | Nonsense Mutation (SNP) | VAF 20/60 reads (33%) | catalogued as COSV100334792; called by muse, mutect2, varscan2
- TMEM91 | c.503C>A p.S168Y | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV99652662; called by muse, mutect2, varscan2
- TNIP1 | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.922); catalogued as COSV100161312, COSV100161356; called by muse, mutect2, varscan2
- TPD52 | c.4G>A p.D2N | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.005); catalogued as COSV100990803; called by muse, mutect2, varscan2
- TRPM2 | c.2422G>A p.A808T | Missense Mutation (SNP) | VAF 137/189 reads (72%) | SIFT tolerated (0.21); PolyPhen benign (0.011); catalogued as rs749888700, COSV55973191; called by muse, mutect2, varscan2
- TSHZ2 | c.1912G>A p.E638K | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.084); catalogued as COSV100296107; called by muse, mutect2, varscan2
- USP28 | c.1813A>T p.I605F | Missense Mutation (SNP) | VAF 50/83 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99135254; called by muse, mutect2, varscan2
- USP47 | c.904C>T p.Q302* (on ENST00000399455 / NM_001372095.1; = p.Q214* on NM_017944.4 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 18/37 reads (49%) | catalogued as COSV100359569; called by muse, mutect2, varscan2
- WBP1L | c.845A>G p.D282G | Missense Mutation (SNP) | VAF 66/132 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV100882470; called by muse, mutect2, varscan2
- WWP2 | c.427G>C p.G143R | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.404); catalogued as COSV63123169, COSV63125518; called by muse, mutect2, varscan2
- YLPM1 | c.709C>T p.Q237* | Nonsense Mutation (SNP) | VAF 23/101 reads (23%) | catalogued as COSV99459720; called by muse, mutect2, varscan2
- ZBED6CL | c.455A>G p.Q152R | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT tolerated (0.59); PolyPhen benign (0.015); catalogued as rs1338814610, COSV100550521; called by muse, mutect2, varscan2
- ZKSCAN8 | c.749A>T p.E250V | Missense Mutation (SNP) | VAF 41/121 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100362914; called by muse, mutect2, varscan2
- ZNF43 | c.443T>C p.F148S | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as rs761526362, COSV100731818, COSV61686185; called by muse, mutect2, varscan2
- ZNF672 | c.1188G>T p.E396D | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.067); catalogued as COSV100129202; called by muse, mutect2, varscan2
- ZNF792 | c.1343G>A p.R448Q | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.222); catalogued as rs771402255, COSV101289706; called by muse, mutect2
- ZSWIM4 | c.2159C>T p.T720I | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99584903; called by muse, mutect2, varscan2
- ACMSD | c.56dup p.R20Efs*42 | Frame Shift Ins (INS) | VAF 10/47 reads (21%) | called by mutect2, pindel, varscan2
- BAZ1A | c.261dup p.P88Sfs*16 | Frame Shift Ins (INS) | VAF 515/829 reads (62%) | called by mutect2, pindel, varscan2
- DNAAF2 | c.2135dup p.A713Sfs*3 | Frame Shift Ins (INS) | VAF 15/102 reads (15%) | called by mutect2, pindel, varscan2
- KDM5A | c.3569del p.P1190Lfs*19 | Frame Shift Del (DEL) | VAF 31/209 reads (15%) | called by mutect2, pindel, varscan2
- MAMLD1 | c.343del p.I115* | Frame Shift Del (DEL) | VAF 65/108 reads (60%) | called by mutect2, pindel, varscan2
- MUC5B | c.7132G>A p.E2378K | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.79); PolyPhen benign (0.02); called by mutect2, varscan2
- TNFRSF1A | c.1094del p.N365Tfs*14 | Frame Shift Del (DEL) | VAF 12/32 reads (38%) | called by mutect2, varscan2
- ABCC1 | c.3318C>T p.I1106= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as rs758983579, COSV100579568; called by muse, mutect2, varscan2
- BAZ1B | c.3870C>A p.G1290= | Silent (SNP) | VAF 77/155 reads (50%) | catalogued as COSV100289790; called by muse, mutect2, varscan2
- CACNA1H | c.1110C>T p.A370= | Silent (SNP) | VAF 11/66 reads (17%) | catalogued as rs1037578858, COSV100672555; called by muse, mutect2
- CASR | c.579G>A p.Q193= | Silent (SNP) | VAF 40/170 reads (24%) | catalogued as rs933291696, COSV99072549, COSV99948980; ClinVar: likely benign; called by muse, mutect2, varscan2
- COL25A1 | c.303C>A p.S101= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as COSV101211424, COSV67658824; called by muse, mutect2, varscan2
- DEFB128 | c.258C>A p.P86= | Silent (SNP) | VAF 52/200 reads (26%) | catalogued as COSV100544436; called by muse, mutect2, varscan2
- DNAH17 | c.9558G>A p.A3186= | Silent (SNP) | VAF 50/86 reads (58%) | catalogued as rs376694280, COSV67749151; called by muse, mutect2, varscan2
- DUS1L | c.627G>A p.G209= | Silent (SNP) | VAF 15/75 reads (20%) | catalogued as COSV100152478; called by muse, mutect2, varscan2
- EP400 | c.5025G>C p.P1675= | Silent (SNP) | VAF 22/60 reads (37%) | catalogued as COSV100201245; called by muse, mutect2, varscan2
- EVI5L | c.1791G>A p.L597= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as COSV99563159; called by muse, mutect2, varscan2
- FAM47A | c.1836C>T p.F612= | Silent (SNP) | VAF 36/54 reads (67%) | catalogued as COSV100649900; called by muse, mutect2, varscan2
- FAM71B | c.756G>T p.T252= | Silent (SNP) | VAF 61/115 reads (53%) | catalogued as COSV100262112; called by muse, mutect2, varscan2
- FBXO41 | c.1416C>A p.R472= | Silent (SNP) | VAF 20/38 reads (53%) | catalogued as COSV99721244; called by muse, mutect2, varscan2
- H1-5 | c.594G>A p.P198= | Silent (SNP) | VAF 25/73 reads (34%) | catalogued as COSV58898866; called by muse, mutect2, varscan2
- IMPDH1 | c.219G>C p.V73= (on ENST00000470772 / NM_001142573.2; = p.V158= on NM_000883.4) | Silent (SNP) | VAF 20/59 reads (34%) | catalogued as COSV100118683; called by muse, mutect2, varscan2
- IVL | c.1698G>A p.L566= | Silent (SNP) | VAF 10/90 reads (11%) | catalogued as COSV100908165; called by muse, mutect2, varscan2
- LINGO4 | c.1284C>T p.G428= | Silent (SNP) | VAF 21/114 reads (18%) | catalogued as rs763684225, COSV100765000; called by muse, mutect2, varscan2
- LYL1 | c.558G>C p.L186= | Silent (SNP) | VAF 3/12 reads (25%) | catalogued as rs945470613, COSV99317094; called by muse, mutect2
- MAGEB6 | c.849G>A p.P283= | Silent (SNP) | VAF 62/83 reads (75%) | catalogued as rs1157318101, COSV66872083; called by muse, mutect2, varscan2
- MGAT2 | c.603G>A p.P201= | Silent (SNP) | VAF 180/284 reads (63%) | catalogued as COSV100023532; called by muse, mutect2, varscan2
- MUC2 | c.348G>A p.T116= | Silent (SNP) | VAF 81/110 reads (74%) | catalogued as rs1486144234; called by muse, mutect2, varscan2
- NPR3 | c.741C>T p.I247= | Silent (SNP) | VAF 65/147 reads (44%) | catalogued as COSV54083925, COSV54087160; called by muse, mutect2, varscan2
- OAS3 | c.696G>A p.L232= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as COSV99966285; called by muse, mutect2, varscan2
- OR1J4 | c.246A>G p.L82= | Silent (SNP) | VAF 77/255 reads (30%) | catalogued as rs1396339286, COSV100534280; called by muse, mutect2, varscan2
- PKN1 | c.2379G>A p.T793= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as rs368511038; called by muse, mutect2
- PLEC | c.10914C>T p.V3638= (on ENST00000322810 / NM_201380.4; = p.V3528= on NM_000445.5) | Silent (SNP) | VAF 37/242 reads (15%) | catalogued as COSV100514220; called by muse, mutect2, varscan2
- PPFIA3 | c.1647C>T p.V549= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV100494926; called by muse, mutect2
- PRKCG | c.282G>A p.T94= | Silent (SNP) | VAF 25/96 reads (26%) | catalogued as rs759030444, COSV54728188; called by muse, mutect2, varscan2
- SASH1 | c.1806C>T p.V602= | Silent (SNP) | VAF 32/111 reads (29%) | catalogued as rs991274312, COSV66561104; called by muse, mutect2, varscan2
- SIPA1L1 | c.4458A>G p.G1486= | Silent (SNP) | VAF 70/140 reads (50%) | catalogued as COSV100665557; called by muse, mutect2, varscan2
- SIX1 | c.483C>T p.T161= | Silent (SNP) | VAF 34/75 reads (45%) | catalogued as rs758128766, COSV55959863; called by muse, mutect2, varscan2
- SLC11A2 | c.1770A>G p.K590= (on ENST00000394904 / NM_001379455.1; = p.K561= on NM_000617.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 28/73 reads (38%) | catalogued as rs934646006, COSV100014724; called by muse, mutect2, varscan2
- SLC22A7 | c.1119G>A p.L373= (on ENST00000372585 / NM_153320.2; = p.L371= on NM_006672.3) | Silent (SNP) | VAF 21/75 reads (28%) | catalogued as COSV99240352; called by muse, mutect2, varscan2
- SLC23A2 | c.339C>T p.C113= | Silent (SNP) | VAF 41/135 reads (30%) | catalogued as rs750051601, COSV100595024; called by muse, mutect2, varscan2
- SLK | c.2145C>T p.I715= | Silent (SNP) | VAF 50/100 reads (50%) | catalogued as rs368294178; called by muse, mutect2, varscan2
- SNIP1 | c.1086C>T p.F362= | Silent (SNP) | VAF 39/146 reads (27%) | catalogued as COSV99953127; called by muse, mutect2, varscan2
- SRCAP | c.846G>C p.L282= | Silent (SNP) | VAF 32/76 reads (42%) | catalogued as COSV52669794, COSV99350155; called by muse, mutect2, varscan2
- THAP3 | c.159C>T p.V53= | Silent (SNP) | VAF 24/88 reads (27%) | catalogued as COSV99275697; called by muse, mutect2, varscan2
- TMEM186 | c.294C>A p.L98= | Silent (SNP) | VAF 19/51 reads (37%) | catalogued as COSV99191144; called by muse, mutect2, varscan2
- TTF1 | c.2717G>A p.*906= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as rs769761538, COSV100524701; called by muse, mutect2, varscan2
- TTF1 | c.2505G>A p.L835= | Silent (SNP) | VAF 42/117 reads (36%) | catalogued as rs540254981, COSV100524703; called by muse, mutect2, varscan2
- UGGT2 | c.12G>A p.A4= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as COSV65025394; called by muse, mutect2, varscan2
- UTP14A | c.2295G>A p.L765= | Silent (SNP) | VAF 33/42 reads (79%) | catalogued as COSV100928961; called by muse, mutect2, varscan2
- ZNF431 | c.924A>T p.I308= | Silent (SNP) | VAF 19/65 reads (29%) | catalogued as COSV100218766; called by muse, mutect2, varscan2
- IGKV1OR22-5 | n.280G>A | RNA (SNP) | VAF 34/135 reads (25%) | called by muse, mutect2, varscan2
- PML | c.1710+846C>T | Intron (SNP) | VAF 55/119 reads (46%) | catalogued as COSV99167138; called by muse, mutect2, varscan2
- PML | c.1710+1193C>T | Intron (SNP) | VAF 46/117 reads (39%) | catalogued as COSV99167139; called by muse, mutect2, varscan2
- PML | c.1710+1341C>G | Intron (SNP) | VAF 77/271 reads (28%) | catalogued as COSV99167140; called by muse, mutect2, varscan2
- SSPOP | n.11661C>T | RNA (SNP) | VAF 26/44 reads (59%) | catalogued as rs374846709, COSV100947458, COSV65127369; called by muse, mutect2, varscan2
- TMEM132E | chr17:34579274 C>G | 5'Flank (SNP) | VAF 5/12 reads (42%) | called by muse, mutect2, varscan2
